Somatic mutation profile of tumor specimen TCGA-X7-A8D8-01A (aliquot TCGA-X7-A8D8-01A-11D-A423-09) from TCGA case TCGA-X7-A8D8, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 53.2 years (19,441 days).
Specimen TCGA-X7-A8D8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5056eb3d-5df3-4143-bb02-3cb09409e6f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8D8-10A (Blood Derived Normal), aliquot TCGA-X7-A8D8-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7342705-18d4-49f5-8357-257ff86677f6

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 116/492 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- AGAP1 | c.165T>A p.D55E | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.785); catalogued as rs755003432; called by muse, mutect2, varscan2
- HDAC4 | c.2238C>A p.F746L | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs753482334, COSV61860486, COSV61869956; called by muse, mutect2, varscan2
- L3MBTL3 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV62386307; called by muse, mutect2
- PSMD9 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1220224880; called by muse, mutect2, varscan2
- PTCH1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV100107938; called by muse, mutect2
- REV3L | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1182357232; called by muse, mutect2, varscan2
- SLC12A1 | c.3209A>G p.Y1070C | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs939499204, CM081798; called by muse, mutect2
- CCK | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CSMD1 | c.8570C>T p.A2857V (on ENST00000520002; = p.A2856V on NM_033225.6) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSRNP1 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSG2 | c.2612G>T p.C871F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- EPG5 | c.7306G>A p.D2436N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FRY | c.6854A>G p.N2285S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- GSC | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, varscan2
- LRP1B | c.2644T>A p.F882I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA3F | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); called by muse, mutect2
- TAS2R1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK3 | c.5541G>T p.L1847= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV56505993; called by muse, mutect2
- NCAM1 | c.1263T>C p.P421= (on ENST00000316851 / NM_181351.5; = p.P411= on NM_000615.7) | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.81G>T p.A27= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV53935539; called by muse, mutect2, varscan2
- RNF180 | c.978T>C p.T326= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- STAG1 | c.3153A>G p.S1051= | Silent (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- TBC1D4 | c.321G>A p.P107= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- ZDHHC6 | c.225C>T p.A75= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs367934020; called by muse, mutect2, varscan2
- OSGIN1 | n.500G>T | RNA (SNP) | VAF 23/218 reads (11%) | catalogued as COSV100652462; called by muse, mutect2
- RFX7 | c.-187C>A | 5'UTR (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100429460; called by muse, mutect2
